Somatic mutation profile of tumor specimen ALCH-ABEP-TTP1-A (aliquot ALCH-ABEP-TTP1-A-1-0-D-A486-36) from ALCHEMIST case ALCH-ABEP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 81.4 years (29,732 days).
Specimen ALCH-ABEP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55f827f7-84f3-4124-876f-bc127760a525.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABEP-NB1-A (Blood Derived Normal), aliquot ALCH-ABEP-NB1-A-1-0-D-A486-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf3b9ad0-69f9-4651-aaee-64a271034da7

The open-access MAF lists 291 somatic variants for this specimen: 170 protein-altering or splice-affecting, 85 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 140, Silent 85, Nonsense Mutation 20, Intron 18, 5'UTR 7, 3'UTR 4, Splice Site 4, RNA 4, Splice Region 4, 5'Flank 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF5 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 32/193 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66613960, COSV66613967; called by muse, mutect2, varscan2
- NF1 | c.1186-1G>C p.X396_splice | Splice Site (SNP) | VAF 48/386 reads (12%) | catalogued as rs876660782, COSV62200893, COSV62215356, COSV62223155; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 74/576 reads (13%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AJAP1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 39/386 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1238425604, COSV65455269; called by muse, mutect2, varscan2
- ANKIB1 | c.2938A>G p.M980V | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs745909984, COSV99729600; called by muse, mutect2, varscan2
- ASB16 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as rs762340517; called by mutect2, varscan2
- BACE2 | c.1231G>C p.V411L | Missense Mutation (SNP) | VAF 38/372 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.42); catalogued as rs1008025148; called by muse, mutect2, varscan2
- C5 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 30/500 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs1319247741; called by muse, mutect2
- C6 | c.1890G>C p.M630I | Missense Mutation (SNP) | VAF 56/565 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs866261314, COSV54715552; called by muse, mutect2
- C8B | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 67/649 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.046); catalogued as rs866880466; called by muse, mutect2, varscan2
- CCDC88A | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 14/180 reads (8%) | catalogued as COSV55070228; called by muse, mutect2
- CCT5 | c.146G>C p.R49T | Missense Mutation (SNP) | VAF 74/841 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as rs1323483213; called by muse, mutect2
- CMYA5 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 12/110 reads (11%) | catalogued as COSV71405619; called by muse, mutect2, varscan2
- CNOT1 | c.6493C>G p.L2165V | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.561); catalogued as COSV55318384; called by muse, mutect2
- COBL | c.2165G>T p.R722I | Missense Mutation (SNP) | VAF 41/295 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV54344823; called by muse, mutect2, varscan2
- CYRIA | c.831G>C p.K277N | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as rs966975936, COSV62863699; called by muse, mutect2, varscan2
- DENND4B | c.3730G>A p.E1244K | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV63412031; called by muse, mutect2
- DNAH8 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767857519; called by muse, mutect2, varscan2
- DPP9 | c.490G>A p.D164N (on ENST00000598800; = p.D193N on NM_139159.5) | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as rs1214113309, COSV53590008, COSV53593505; called by muse, mutect2, varscan2
- DSP | c.2674C>T p.R892C | Missense Mutation (SNP) | VAF 50/414 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs750800025; called by muse, mutect2, varscan2
- FAM200A | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV68808729; called by muse, mutect2, varscan2
- FAXC | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as COSV67602002; called by muse, mutect2
- FBN2 | c.7247G>A p.R2416Q | Missense Mutation (SNP) | VAF 77/816 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs755437836; ClinVar: uncertain significance; called by muse, mutect2
- FBXO38 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 24/373 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs1201701262, COSV57030864; called by muse, mutect2
- FKBP15 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs1387104546, COSV53040524; called by muse, mutect2
- FN1 | c.6845G>A p.G2282E (on ENST00000359671 / NM_001365524.2; = p.G2251E on NM_002026.4) | Missense Mutation (SNP) | VAF 50/530 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749068438; called by muse, mutect2
- GLE1 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 54/416 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as rs759080303, COSV59408913; called by muse, mutect2, varscan2
- HMGCR | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 55/696 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.217); catalogued as rs200260317; called by muse, mutect2
- HNRNPH1 | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 96/498 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1401953147; called by muse, mutect2, varscan2
- HPS6 | c.1051G>C p.D351H | Missense Mutation (SNP) | VAF 95/805 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV54626184; called by muse, mutect2, varscan2
- IGLV8-61 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 40/355 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs751065824, COSV66503139; called by muse, varscan2
- IRF2BP1 | c.1682G>C p.W561S | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100138932; called by muse, mutect2, varscan2
- KIAA0100 | c.1492C>G p.L498V | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.072); catalogued as rs1005448543; called by muse, mutect2, varscan2
- KLF11 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 18/179 reads (10%) | catalogued as COSV100007713, COSV100007842; called by muse, mutect2, varscan2
- LRIG3 | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 37/357 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as rs752462590; called by muse, mutect2, varscan2
- ME1 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as rs779943005; called by muse, mutect2, varscan2
- MON1A | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 13/131 reads (10%) | catalogued as COSV56562816; called by muse, mutect2, varscan2
- MORF4L1 | c.292G>A p.E98K (on ENST00000331268 / NM_206839.2; = p.E59K on NM_006791.4) | Missense Mutation (SNP) | VAF 50/493 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV58704427; called by muse, mutect2, varscan2
- MPO | c.179C>G p.S60W | Missense Mutation (SNP) | VAF 89/720 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV56561295, COSV99832376; called by muse, mutect2, varscan2
- MR1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 46/782 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.072); catalogued as rs760201157; called by muse, mutect2
- NLRC5 | c.5306C>G p.A1769G | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV52657025, COSV99348588; called by muse, mutect2
- NOS1 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.19); catalogued as COSV57621482; called by muse, mutect2, varscan2
- NPC1 | c.3591+3G>A | Splice Region (SNP) | VAF 72/572 reads (13%) | catalogued as CS015202; called by muse, mutect2, varscan2
- NRG3 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 40/338 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as rs1002662503; called by muse, mutect2, varscan2
- OR52K1 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 42/488 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs552943528, COSV56903135; called by muse, mutect2
- PADI2 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as rs191431667; called by muse, mutect2, varscan2
- PCDHGB5 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 48/433 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.379); catalogued as COSV53919558; called by muse, mutect2, varscan2
- PIK3R6 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100266326; called by muse, mutect2, varscan2
- PKHD1 | c.5695C>T p.Q1899* | Nonsense Mutation (SNP) | VAF 76/542 reads (14%) | catalogued as COSV61859037; called by muse, mutect2, varscan2
- PLEKHG4B | c.2578G>A p.D860N (on ENST00000283426; = p.D1216N on NM_052909.5) | Missense Mutation (SNP) | VAF 33/453 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); catalogued as rs753179496, COSV52047981; called by muse, mutect2
- PRKACG | c.81C>A p.F27L | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV55259491; called by muse, mutect2
- PRKDC | c.10558G>T p.E3520* | Nonsense Mutation (SNP) | VAF 50/308 reads (16%) | catalogued as COSV58044908; called by muse, mutect2, varscan2
- PRR14L | c.5440G>C p.D1814H | Missense Mutation (SNP) | VAF 27/311 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as COSV57885333; called by muse, mutect2
- PTCD1 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.444); catalogued as rs1394411797; called by muse, mutect2, varscan2
- PYROXD1 | c.109G>C p.D37H | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV53711815; called by muse, mutect2
- RNF220 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as rs954865074, COSV62407155; called by muse, mutect2
- SBNO1 | c.3503G>A p.G1168E (on ENST00000420886; = p.G1167E on NM_018183.5) | Missense Mutation (SNP) | VAF 16/368 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as rs915856209; called by muse, mutect2
- SHANK1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53244165, COSV53263579; called by muse, mutect2
- SLAMF9 | c.815T>C p.M272T | Missense Mutation (SNP) | VAF 38/327 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV63637435; called by muse, mutect2, varscan2
- SLC17A2 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 42/477 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as rs1394476548, COSV99613880; called by muse, mutect2
- SLF1 | c.1717C>T p.L573F | Missense Mutation (SNP) | VAF 45/510 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV54371607; called by muse, mutect2
- STAT3 | c.1339C>G p.H447D | Missense Mutation (SNP) | VAF 76/715 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV52883556; called by muse, mutect2, varscan2
- TCN1 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 60/568 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as rs375129617; called by muse, varscan2
- TINAG | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.999); catalogued as rs781049566, COSV52508557; called by muse, mutect2
- TLK1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV62632301; called by muse, mutect2, varscan2
- TOPAZ1 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.501); catalogued as rs1360890104; called by muse, mutect2, varscan2
- TRIM28 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs1366499037; called by muse, mutect2
- TRIO | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 48/384 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as rs764278202; called by muse, mutect2, varscan2
- USP13 | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); catalogued as COSV55864564; called by muse, mutect2
- USP29 | c.2104G>A p.E702K | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.085); catalogued as COSV99518644; called by muse, mutect2, varscan2
- UTP14A | c.1421G>A p.R474K | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs1193219579; called by muse, mutect2
- VANGL2 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 52/550 reads (9%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.988); catalogued as COSV63605084; called by muse, mutect2
- ABCA7 | c.6111C>A p.F2037L | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- AC073896.1 | c.506-1G>C p.X169_splice | Splice Site (SNP) | VAF 20/212 reads (9%) | called by muse, mutect2
- ADAMTS13 | c.3949C>G p.P1317A | Missense Mutation (SNP) | VAF 47/354 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ADCY8 | c.1321G>T p.E441* | Nonsense Mutation (SNP) | VAF 31/262 reads (12%) | called by muse, mutect2, varscan2
- AGGF1 | c.1844+1G>T p.X615_splice | Splice Site (SNP) | VAF 57/622 reads (9%) | called by muse, mutect2
- AGMO | c.960C>T p.V320= | Splice Region (SNP) | VAF 25/168 reads (15%) | called by muse, mutect2, varscan2
- AGXT | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 24/302 reads (8%) | called by muse, mutect2
- ARHGAP28 | c.1577C>T p.S526L (on ENST00000383472 / NM_001366230.1; = p.S367L on NM_001010000.3) | Missense Mutation (SNP) | VAF 59/452 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ATXN7L2 | c.584G>C p.R195T | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.149); called by muse, mutect2
- BCL2A1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 52/476 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- BCL9L | c.3997G>A p.E1333K | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- BCLAF1 | c.2483dup p.R829Efs*22 | Frame Shift Ins (INS) | VAF 57/454 reads (13%) | called by mutect2, pindel, varscan2
- CACNA2D1 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 84/787 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCDC146 | c.2062G>C p.E688Q | Missense Mutation (SNP) | VAF 46/413 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- CCDC88A | c.4816G>A p.E1606K (on ENST00000436346 / NM_001365480.1; = p.E1578K on NM_018084.5) | Missense Mutation (SNP) | VAF 34/276 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CELSR3 | c.8135G>A p.G2712E | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.439); called by muse, mutect2
- CHD3 | c.5095G>C p.E1699Q (on ENST00000330494 / NM_001005273.3; = p.E1665Q on NM_005852.4) | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- CHRNA4 | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 66/639 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- CPEB1 | c.677G>C p.R226T (on ENST00000617958; = p.R166T on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- CPLANE2 | c.26C>A p.S9* | Nonsense Mutation (SNP) | VAF 41/324 reads (13%) | called by muse, mutect2, varscan2
- CSRP1 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 21/279 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DDX46 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 16/146 reads (11%) | called by muse, varscan2
- DHX38 | c.674C>G p.S225* | Nonsense Mutation (SNP) | VAF 27/174 reads (16%) | called by muse, mutect2, varscan2
- DMXL2 | c.6095A>T p.D2032V | Missense Mutation (SNP) | VAF 39/325 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- EIF5B | c.1761G>A p.M587I | Missense Mutation (SNP) | VAF 36/292 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, varscan2
- ELAVL3 | c.627G>C p.K209N | Missense Mutation (SNP) | VAF 46/454 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EML6 | c.4553C>T p.S1518L | Missense Mutation (SNP) | VAF 36/476 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- EPS8L2 | c.1358G>C p.R453P | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.037); called by muse, mutect2
- ERAP1 | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 36/456 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- EXT1 | c.505C>T p.Q169* | Nonsense Mutation (SNP) | VAF 60/476 reads (13%) | called by muse, mutect2, varscan2
- EYS | c.7881G>C p.E2627D | Missense Mutation (SNP) | VAF 18/251 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.144); called by muse, mutect2
- FBXL19 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1396C>T p.H466Y | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); called by muse, varscan2
- GPR18 | c.179_225del p.Y60Sfs*11 | Frame Shift Del (DEL) | VAF 44/246 reads (18%) | called by mutect2, pindel
- HECTD4 | c.10888G>C p.E3630Q | Missense Mutation (SNP) | VAF 48/498 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IDI1 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 54/410 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGFBP4 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- INO80D | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); called by muse, mutect2
- IPO7 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- IPP | c.1553C>T p.S518L | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, varscan2
- IRX2 | c.854C>G p.S285W | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ISL2 | c.879G>C p.E293D | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KCNJ3 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, varscan2
- KCNS2 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 80/740 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KIAA0100 | c.1275C>G p.I425M | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); called by muse, varscan2
- KLHDC10 | c.931+1G>T p.X311_splice | Splice Site (SNP) | VAF 13/152 reads (9%) | called by muse, mutect2
- LAMTOR2 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 24/492 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.648); called by muse, mutect2
- LARP4 | c.1418C>G p.P473R | Missense Mutation (SNP) | VAF 24/267 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); called by muse, mutect2
- LIPE | c.3133G>A p.E1045K | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.054); called by muse, varscan2
- MOB3A | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- MSS51 | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 45/316 reads (14%) | called by muse, mutect2, varscan2
- NIPBL | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 54/498 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NMT1 | c.1135G>T p.E379* | Nonsense Mutation (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- NOP58 | c.955C>G p.L319V | Missense Mutation (SNP) | VAF 30/210 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- NUCB2 | c.761-4T>C | Splice Region (SNP) | VAF 22/141 reads (16%) | called by muse, mutect2, varscan2
- PCDHB9 | c.1508T>C p.L503P | Missense Mutation (SNP) | VAF 100/936 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PCDHGA10 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE8B | c.1539G>C p.L513F | Missense Mutation (SNP) | VAF 47/582 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.396); called by muse, mutect2
- PDHA2 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- PDIA3 | c.1347-6C>A | Splice Region (SNP) | VAF 24/248 reads (10%) | called by muse, mutect2
- PKD1L2 | c.2038A>T p.I680F | Missense Mutation (SNP) | VAF 30/440 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2
- PPP2R3C | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 32/420 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PTPRJ | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- RANBP3 | c.1239G>C p.K413N (on ENST00000340578 / NM_007322.3; = p.K408N on NM_003624.3) | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RANBP3L | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 34/328 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); called by muse, mutect2
- RETSAT | c.454C>G p.P152A | Missense Mutation (SNP) | VAF 37/373 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RHO | c.39C>G p.F13L | Missense Mutation (SNP) | VAF 32/296 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RPS20 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 49/464 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RYR2 | c.14116C>T p.Q4706* | Nonsense Mutation (SNP) | VAF 14/205 reads (7%) | called by muse, mutect2
- S100A4 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 13/304 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SAXO1 | c.215C>G p.S72* | Nonsense Mutation (SNP) | VAF 19/100 reads (19%) | called by muse, mutect2
- SECISBP2 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 43/672 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SH3TC2 | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 71/668 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC25A29 | c.582G>T p.L194F (on ENST00000359232 / NM_001039355.3; = p.L128F on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SLC26A8 | c.879C>G p.I293M | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SMG1 | c.1406C>G p.P469R | Missense Mutation (SNP) | VAF 23/826 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2
- SON | c.4064C>T p.S1355L | Missense Mutation (SNP) | VAF 49/421 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAT3 | c.1288C>G p.L430V | Missense Mutation (SNP) | VAF 65/622 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SYNE2 | c.5245G>A p.E1749K | Missense Mutation (SNP) | VAF 77/678 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- SYNPO2L | c.1051G>A p.D351N (on ENST00000394810 / NM_001114133.3; = p.D127N on NM_024875.5) | Missense Mutation (SNP) | VAF 30/318 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- TATDN2 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); called by muse, mutect2
- TGFB2 | c.1007A>T p.H336L | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- THOC3 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 27/476 reads (6%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2
- TIGD6 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.548); called by muse, mutect2
- TMEM132C | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TMEM170A | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMPRSS13 | c.1718G>A p.G573E | Missense Mutation (SNP) | VAF 51/353 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TTLL5 | c.2758C>G p.Q920E | Missense Mutation (SNP) | VAF 26/363 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.022); called by muse, mutect2
- TTN | c.42905C>T p.S14302L (on ENST00000591111; = p.S6878L on NM_003319.4) | Missense Mutation (SNP) | VAF 18/184 reads (10%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UMODL1 | c.1310C>G p.S437C | Missense Mutation (SNP) | VAF 54/413 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- UPF1 | c.1240G>C p.V414L (on ENST00000599848 / NM_001297549.2; = p.V403L on NM_002911.4) | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- WWC1 | c.672C>G p.I224M | Missense Mutation (SNP) | VAF 31/326 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2
- ZFAND1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF469 | c.811G>T p.V271F | Missense Mutation (SNP) | VAF 91/435 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- ZNF638 | c.1511G>A p.R504K | Missense Mutation (SNP) | VAF 48/460 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF721 | c.2090C>G p.S697* (on ENST00000338977; = p.S709* on NM_133474.4) | Nonsense Mutation (SNP) | VAF 21/173 reads (12%) | called by muse, mutect2, varscan2
- ZNF883 | c.334C>G p.L112V | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2
- ZSCAN29 | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 31/312 reads (10%) | called by muse, mutect2, varscan2
- ACSM2A | c.1593G>A p.V531= (on ENST00000219054; = p.V452= on NM_001308169.2) | Silent (SNP) | VAF 24/375 reads (6%) | catalogued as COSV54583138; called by muse, mutect2
- ADRB2 | c.378G>A p.V126= | Silent (SNP) | VAF 70/627 reads (11%) | catalogued as rs756597229; called by muse, mutect2, varscan2
- AHCTF1 | c.72T>C p.C24= | Silent (SNP) | VAF 32/221 reads (14%) | called by muse, mutect2, varscan2
- AHNAK2 | c.4677G>A p.V1559= | Silent (SNP) | VAF 33/634 reads (5%) | called by muse, mutect2
- ATP12A | c.1146C>T p.L382= | Silent (SNP) | VAF 36/206 reads (17%) | catalogued as rs778320466, COSV54514126; called by muse, varscan2
- BCL9L | c.3441G>A p.L1147= | Silent (SNP) | VAF 91/764 reads (12%) | called by muse, mutect2, varscan2
- BMPER | c.1830G>A p.Q610= | Silent (SNP) | VAF 98/804 reads (12%) | called by muse, mutect2, varscan2
- C2 | c.960C>T p.I320= | Silent (SNP) | VAF 74/562 reads (13%) | called by muse, mutect2, varscan2
- CACNA1I | c.3897C>T p.L1299= | Silent (SNP) | VAF 15/158 reads (9%) | called by muse, mutect2, varscan2
- CAMK4 | c.195G>A p.Q65= | Silent (SNP) | VAF 28/340 reads (8%) | called by muse, mutect2
- CCDC141 | c.48C>T p.V16= | Silent (SNP) | VAF 18/286 reads (6%) | called by muse, mutect2
- CCT6A | c.942C>T p.R314= | Silent (SNP) | VAF 23/247 reads (9%) | called by muse, mutect2, varscan2
- CD163 | c.2988G>A p.V996= | Silent (SNP) | VAF 38/393 reads (10%) | called by muse, mutect2, varscan2
- CD58 | c.21G>A p.A7= | Silent (SNP) | VAF 17/173 reads (10%) | catalogued as COSV65651764; called by muse, mutect2, varscan2
- CDC37 | c.573C>G p.V191= | Silent (SNP) | VAF 39/335 reads (12%) | catalogued as COSV55770015; called by muse, mutect2, varscan2
- CENPT | c.1026G>C p.V342= | Silent (SNP) | VAF 114/600 reads (19%) | called by muse, mutect2, varscan2
- CEP192 | c.6579G>A p.V2193= | Silent (SNP) | VAF 30/208 reads (14%) | called by muse, mutect2, varscan2
- CLDN2 | c.255G>A p.V85= | Silent (SNP) | VAF 42/194 reads (22%) | catalogued as rs199729528; called by muse, mutect2, varscan2
- CNNM3 | c.975C>T p.F325= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as rs749651383; called by muse, varscan2
- COL5A3 | c.1620C>T p.L540= | Silent (SNP) | VAF 26/229 reads (11%) | called by muse, mutect2, varscan2
- CREBBP | c.510G>A p.Q170= | Silent (SNP) | VAF 50/724 reads (7%) | called by muse, mutect2
- CRYGC | c.420G>A p.R140= | Silent (SNP) | VAF 54/389 reads (14%) | called by muse, mutect2, varscan2
- DIS3L | c.1371G>T p.V457= (on ENST00000319212 / NM_001143688.3; = p.V374= on NM_133375.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 72/397 reads (18%) | called by muse, mutect2, varscan2
- DISP2 | c.1533C>T p.F511= | Silent (SNP) | VAF 24/372 reads (6%) | called by muse, mutect2
- DND1 | c.42G>A p.V14= | Silent (SNP) | VAF 70/753 reads (9%) | called by muse, mutect2
- EGR1 | c.865C>T p.L289= | Silent (SNP) | VAF 44/474 reads (9%) | called by muse, mutect2
- EXOC4 | c.2824C>T p.L942= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as rs1362767840, COSV54085209; called by muse, mutect2, varscan2
- FLG | c.6324G>A p.A2108= | Silent (SNP) | VAF 94/1139 reads (8%) | catalogued as rs763227797; called by muse, mutect2
- FLNC | c.291G>A p.L97= | Silent (SNP) | VAF 24/722 reads (3%) | called by muse, mutect2
- FNDC8 | c.735G>A p.L245= | Silent (SNP) | VAF 68/478 reads (14%) | called by muse, mutect2, varscan2
- FOXD4L4 | c.1140C>T p.L380= | Silent (SNP) | VAF 15/117 reads (13%) | called by mutect2, varscan2
- FOXN2 | c.126G>A p.P42= | Silent (SNP) | VAF 61/515 reads (12%) | catalogued as rs755184660, COSV61319830; called by muse, mutect2, varscan2
- GALC | c.135C>T p.L45= | Silent (SNP) | VAF 30/439 reads (7%) | catalogued as rs1304312287; called by muse, mutect2
- GUSB | c.1797G>A p.T599= | Silent (SNP) | VAF 32/287 reads (11%) | catalogued as rs552724524; called by mutect2, varscan2
- HEATR5A | c.1293C>T p.L431= | Silent (SNP) | VAF 22/348 reads (6%) | called by muse, mutect2
- HGSNAT | c.1797G>A p.L599= | Silent (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2, varscan2
- HRH4 | c.561C>T p.V187= | Silent (SNP) | VAF 71/580 reads (12%) | catalogued as rs748784371; called by muse, mutect2, varscan2
- HTR7 | c.1439G>A p.*480= | Silent (SNP) | VAF 22/219 reads (10%) | called by muse, varscan2
- IL6R | c.1128C>T p.F376= | Silent (SNP) | VAF 49/412 reads (12%) | catalogued as rs751402081, COSV59816415; called by muse, mutect2, varscan2
- IRF2BP1 | c.1276C>T p.L426= | Silent (SNP) | VAF 53/344 reads (15%) | catalogued as rs1394614111; called by muse, mutect2, varscan2
- KCTD16 | c.684C>G p.L228= | Silent (SNP) | VAF 73/777 reads (9%) | catalogued as COSV101568665; called by muse, mutect2
- LRRN3 | c.993C>T p.F331= | Silent (SNP) | VAF 16/163 reads (10%) | called by muse, mutect2, varscan2
- LTB4R2 | c.675C>T p.F225= (on ENST00000528054; = p.F194= on NM_019839.5) | Silent (SNP) | VAF 55/402 reads (14%) | catalogued as rs779308801; called by muse, mutect2, varscan2
- LTBP3 | c.3141G>C p.R1047= | Silent (SNP) | VAF 57/469 reads (12%) | called by muse, mutect2, varscan2
- LTBP3 | c.3033G>A p.V1011= | Silent (SNP) | VAF 92/907 reads (10%) | catalogued as COSV54212493; called by muse, mutect2, varscan2
- MDGA2 | c.738C>G p.V246= | Silent (SNP) | VAF 13/158 reads (8%) | called by muse, mutect2
- MECP2 | c.999G>A p.G333= | Silent (SNP) | VAF 50/294 reads (17%) | called by muse, mutect2, varscan2
- MOB3A | c.171G>C p.L57= | Silent (SNP) | VAF 18/119 reads (15%) | catalogued as COSV63865734; called by muse, mutect2, varscan2
- MS4A15 | c.321C>T p.G107= (on ENST00000405633 / NM_001098835.2; = p.G14= on NM_152717.3) | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs1176343866, COSV61961483; called by muse, mutect2, varscan2
- MTRES1 | c.510G>A p.L170= | Silent (SNP) | VAF 15/223 reads (7%) | catalogued as COSV60968859; called by muse, mutect2
- MXI1 | c.21C>T p.I7= | Silent (SNP) | VAF 16/151 reads (11%) | called by muse, mutect2, varscan2
- MYH7 | c.4347C>T p.F1449= | Silent (SNP) | VAF 34/320 reads (11%) | catalogued as rs182311329; ClinVar: likely benign; called by muse, mutect2, varscan2
- NR2C2 | c.108G>A p.Q36= (on ENST00000393102; = p.Q55= on NM_003298.5) | Silent (SNP) | VAF 63/406 reads (16%) | called by muse, mutect2, varscan2
- NUDT1 | c.459G>A p.K153= (on ENST00000397048 / NM_198952.1; = p.K130= on NM_002452.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 50/501 reads (10%) | catalogued as rs747740732, COSV56130931, COSV99770937; called by muse, mutect2, varscan2
- OR14A2 | c.672G>A p.L224= | Silent (SNP) | VAF 24/230 reads (10%) | catalogued as rs1030439956; called by muse, mutect2, varscan2
- OR2L13 | c.864C>T p.I288= | Silent (SNP) | VAF 29/283 reads (10%) | catalogued as rs1342842302, COSV100813852; called by muse, mutect2, varscan2
- PACS2 | c.1080G>A p.L360= | Silent (SNP) | VAF 14/138 reads (10%) | called by muse, mutect2, varscan2
- PCDHGA12 | c.1596G>A p.V532= | Silent (SNP) | VAF 24/272 reads (9%) | called by muse, mutect2
- PCDHGA9 | c.285C>G p.L95= | Silent (SNP) | VAF 20/222 reads (9%) | catalogued as COSV53918444; called by muse, mutect2
- PDE6B | c.1704G>A p.T568= | Silent (SNP) | VAF 65/617 reads (11%) | catalogued as rs143615664; called by muse, mutect2, varscan2
- POLR1A | c.2685G>A p.Q895= | Silent (SNP) | VAF 22/268 reads (8%) | called by muse, mutect2
- POTEI | c.2844C>T p.I948= | Silent (SNP) | VAF 61/578 reads (11%) | called by muse, mutect2, varscan2
- PRMT1 | c.1053C>T p.I351= | Silent (SNP) | VAF 65/573 reads (11%) | catalogued as rs746072676; called by muse, mutect2, varscan2
- PRR36 | c.132C>A p.L44= | Silent (SNP) | VAF 26/166 reads (16%) | called by muse, mutect2, varscan2
- SEC16A | c.1269C>G p.L423= | Silent (SNP) | VAF 22/278 reads (8%) | called by muse, mutect2
- SH3D19 | c.1860C>T p.F620= | Silent (SNP) | VAF 34/286 reads (12%) | catalogued as COSV100456026; called by muse, varscan2
- SIGIRR | c.36C>T p.L12= | Silent (SNP) | VAF 60/490 reads (12%) | catalogued as rs1404695701; called by muse, mutect2, varscan2
- SKA3 | c.1068C>G p.L356= | Silent (SNP) | VAF 36/263 reads (14%) | called by muse, mutect2, varscan2
- SLC22A5 | c.432C>G p.L144= | Silent (SNP) | VAF 62/684 reads (9%) | called by muse, mutect2
- SLCO2A1 | c.1098C>T p.F366= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV60484745; called by muse, mutect2
- SLIT3 | c.615G>A p.P205= | Silent (SNP) | VAF 58/469 reads (12%) | catalogued as rs773850765; called by muse, mutect2, varscan2
- SNX11 | c.411C>T p.A137= | Silent (SNP) | VAF 71/616 reads (12%) | called by muse, mutect2, varscan2
- SPOCK2 | c.645C>T p.F215= | Silent (SNP) | VAF 56/455 reads (12%) | catalogued as COSV58038459; called by muse, mutect2, varscan2
- SYF2 | c.126G>A p.L42= | Silent (SNP) | VAF 38/385 reads (10%) | catalogued as rs778445714; called by muse, mutect2
- SYT13 | c.153G>A p.A51= | Silent (SNP) | VAF 40/468 reads (9%) | catalogued as rs573392398, COSV50072925; called by muse, mutect2
- TDRD5 | c.1722G>C p.L574= | Silent (SNP) | VAF 22/243 reads (9%) | called by muse, mutect2
- THBS4 | c.2139C>T p.I713= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as rs1260682690; called by muse, mutect2, varscan2
- TMEM134 | c.564C>T p.F188= | Silent (SNP) | VAF 50/409 reads (12%) | called by muse, mutect2, varscan2
- TMEM200B | c.351C>G p.L117= | Silent (SNP) | VAF 19/145 reads (13%) | called by muse, mutect2, varscan2
- TXNL1 | c.12G>A p.V4= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV54181293; called by muse, mutect2, varscan2
- UGT3A2 | c.289C>T p.L97= | Silent (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2
- UMODL1 | c.1374C>T p.L458= | Silent (SNP) | VAF 44/401 reads (11%) | called by muse, mutect2, varscan2
- VSX2 | c.192G>A p.A64= | Silent (SNP) | VAF 14/269 reads (5%) | called by muse, mutect2
- ZGRF1 | c.918G>A p.K306= | Silent (SNP) | VAF 35/219 reads (16%) | called by muse, mutect2, varscan2
- ZNF354C | c.981C>T p.L327= | Silent (SNP) | VAF 44/542 reads (8%) | called by muse, mutect2
- AC107023.1 | n.25+511G>A | Intron (SNP) | VAF 22/160 reads (14%) | called by muse, mutect2, varscan2
- ANKRD42 | c.502+1621G>C | Intron (SNP) | VAF 30/231 reads (13%) | called by muse, mutect2, varscan2
- ANXA2P2 | n.138C>G | RNA (SNP) | VAF 48/491 reads (10%) | called by muse, mutect2, varscan2
- ATP5MC3 | c.-28C>G | 5'UTR (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2
- BEND6 | chr6:56954409 C>G | 5'Flank (SNP) | VAF 16/183 reads (9%) | called by muse, mutect2
- C8orf44-SGK3 | c.-121-26004C>G | Intron (SNP) | VAF 44/328 reads (13%) | called by muse, mutect2, varscan2
- CALCA | chr11:14967703 G>A | 3'Flank (SNP) | VAF 50/430 reads (12%) | called by muse, mutect2, varscan2
- DHDDS | c.323+34C>T | Intron (SNP) | VAF 54/418 reads (13%) | catalogued as rs762862807; called by muse, mutect2, varscan2
- ERMAP | c.584-20C>G | Intron (SNP) | VAF 26/156 reads (17%) | called by muse, varscan2
- FBLN7 | c.670+81C>G | Intron (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- FBXL21P | n.1430A>G | RNA (SNP) | VAF 74/829 reads (9%) | called by muse, mutect2
- FUT8 | c.-326+72C>T | Intron (SNP) | VAF 57/429 reads (13%) | catalogued as rs1009387450; called by muse, mutect2, varscan2
- GSN-AS1 | chr9:121286143 G>A | 5'Flank (SNP) | VAF 32/249 reads (13%) | called by muse, mutect2, varscan2
- HLA-DMB | c.776-35G>A | Intron (SNP) | VAF 27/252 reads (11%) | called by muse, mutect2, varscan2
- HMGCL | c.-10C>G | 5'UTR (SNP) | VAF 42/388 reads (11%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.240-23876G>T | Intron (SNP) | VAF 42/335 reads (13%) | called by muse, mutect2, varscan2
- IL19 | c.363+51G>C | Intron (SNP) | VAF 19/211 reads (9%) | catalogued as rs1287387457; called by muse, mutect2
- MMAB | c.*2801C>T | 3'UTR (SNP) | VAF 17/143 reads (12%) | catalogued as rs894703389; called by muse, mutect2, varscan2
- MON1A | c.278+47G>C | Intron (SNP) | VAF 15/115 reads (13%) | catalogued as rs755166801; called by muse, mutect2, varscan2
- NEFH | c.-18C>A | 5'UTR (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- PEX16 | c.-16C>T | 5'UTR (SNP) | VAF 47/547 reads (9%) | called by muse, mutect2
- PEX5L | c.94-2472G>A | Intron (SNP) | VAF 31/278 reads (11%) | called by muse, mutect2, varscan2
- RAPGEF6 | c.2239+30G>T | Intron (SNP) | VAF 40/287 reads (14%) | called by muse, mutect2, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 17/304 reads (6%) | catalogued as rs910081914; called by muse, mutect2
- SEMA6C | c.*47C>T | 3'UTR (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- SLC7A5P2 | n.441C>T | RNA (SNP) | VAF 58/1140 reads (5%) | called by muse, mutect2
- SSX6P | n.108G>C | RNA (SNP) | VAF 48/299 reads (16%) | called by muse, mutect2, varscan2
- STAB1 | c.7291-35C>T | Intron (SNP) | VAF 54/482 reads (11%) | catalogued as rs202105447; called by muse, mutect2, varscan2
- STRA6 | c.430+21G>C | Intron (SNP) | VAF 22/175 reads (13%) | called by muse, mutect2, varscan2
- TBC1D12 | c.-3C>T | 5'UTR (SNP) | VAF 29/231 reads (13%) | catalogued as rs776687705, COSV56552223; called by muse, mutect2, varscan2
- TPM1 | c.240+4423G>C | Intron (SNP) | VAF 34/367 reads (9%) | catalogued as COSV99147790; called by muse, mutect2
- VAPB | c.*39C>T | 3'UTR (SNP) | VAF 58/682 reads (9%) | called by muse, mutect2
- WFDC9 | c.*16C>T | 3'UTR (SNP) | VAF 23/180 reads (13%) | catalogued as rs865790720; called by muse, mutect2, varscan2
- ZFP90 | c.161-85C>G | Intron (SNP) | VAF 46/241 reads (19%) | called by muse, varscan2
- ZNF615 | c.-9T>G | 5'UTR (SNP) | VAF 29/211 reads (14%) | called by muse, mutect2, varscan2
- ZNF853 | c.-99G>A | 5'UTR (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
